TARGET case TARGET-40-PAUTYB — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3d6d7d55-0897-5df4-a8b1-81bd5a0ca0fa

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 12 years; Vital status: Dead; Days to death: 537 days (1.5 years).

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Classification of tumor: primary; Age at diagnosis: 12.1 years (4,418 days); Year of diagnosis: 2012; Metastasis at diagnosis: No Metastasis; Days to last follow up: 537 days (1.5 years).
   Treatment given: Protocol identifier: AOST06B1.

Follow-up (2 entries)
- Days to follow up: 527 days (1.4 years); Progression or recurrence: Yes; Days to progression: 527 days (1.4 years); Days to first event: 527 days (1.4 years); First event: Relapse.
- Days to follow up: 537 days (1.5 years); Year of follow up: 2013.

Biospecimens (2 samples)
- Sample TARGET-40-PAUTYB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-PAUTYB-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_20230709.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 537
- Disease at diagnosis: Non-metastatic (confirmed)
- Primary tumor site: Leg/foot
- Specific tumor site: Tibia

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-PAUTYB-01A-01:
- Specimen Type: Frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 99
- % Non Tumor Nuclei: Top from Biopsy: 1
- % Cellular Tumor: Top from Biopsy: 99
- % Normal: Top from Biopsy: 1
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 0
- % Tumor Nuclei: Bottom from Biopsy: 99
- % Non Tumor Nuclei: Bottom from Biopsy: 1
- % Cellular Tumor: Bottom from Biopsy: 94
- % Normal: Bottom from Biopsy: 1
- % Stroma: Bottom from Biopsy: 0
- % Necrosis: Bottom from Biopsy: 5
- PASS/FAIL: PASS
